Gene-level copy-number profile of tumor specimen ALCH-B1VH-TTP1-A from ALCHEMIST case ALCH-B1VH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.4 years (24,617 days).
Specimen ALCH-B1VH-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 88cc225d-9870-41d1-878f-5d2acd441e36.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1VH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/a58d3cc7-4437-4c48-912f-c46998535a66

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 619; copy number 2: 57,283; copy number 3: 455; copy number 4: 6; copy number 5: 6; copy number 6: 3; copy number 9: 1; copy number 32: 3.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:28,870,483–28,881,835, 2 genes (within-gene range 0–2): AL009181.1, Y_RNA.
- chr4:112,513,516–112,516,180, 1 gene (within-gene range 0–2): NEUROG2.
- chr7:56,991,888–57,020,273, 2 genes: TNRC18P3, SLC29A4P1.
- chr7:130,380,339–130,388,114, 1 gene: CPA1.
- chr12:113,149,858–113,221,094, 8 genes (within-gene range 0–2): CFAP73, Y_RNA, DDX54, MIR7106, Y_RNA, RITA1, AC089999.1, IQCD.
- chr13:19,818,121–19,818,619, 1 gene: ST6GALNAC4P1.
- chr16:675,671–679,777, 3 genes (within-gene range 0–2): RHBDL1, LINC02867, Z92544.2.
- chr16:726,936–741,329, 2 genes (within-gene range 0–2): HAGHL, CIAO3.
- chr17:77,396,984–77,397,054, 1 gene (within-gene range 0–2): MIR4316.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:1,941,172–1,981,338, 2 genes, copy number 5: CSNK1G2, CSNK1G2-AS1.
- chr22:18,846,811–18,947,732, 7 genes, copy number 6–32 (within-gene range 2–32): AC008132.1, BCRP7, FAM230F, AC008103.1, DGCR6, AC007326.4, PRODH.
- chr22:32,121,977–32,143,272, 4 genes, copy number 5: AP1B1P1, Z83839.1, AP1B1P2, Z83839.2.

Autosomal genes at a single copy (total copy number 1): 619. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
